CCDI case PBCFSC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/94cd1a9e-bca2-4bda-b63c-4bc6042c35d7

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Tumor cells, malignant: ICD-O-3 morphology code: 8001/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.0 years (723 days).

Biospecimens (3 samples)
- Sample 0DR3L2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DR3LW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR3MB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
